CCDI case PBCLZE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/e57a2962-931f-496c-b696-449573f7a87e

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 14.8 years (5,409 days).

Biospecimens (3 samples)
- Sample 0DW6AY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DW6B6, 0DW6BN (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
